Somatic mutation profile of tumor specimen 0DSEZL from CCDI case PBCHWK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 16.2 years (5,903 days).
Specimen 0DSEZL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d0b9381-2fa0-4946-9b75-dc0f117f1afe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEYY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a5fa1e9-5061-4109-8de7-b2a1722a3879

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 324/1587 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC149 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 77/1767 reads (4%) | catalogued as rs377438836; called by muse, mutect2
- MYO1D | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 85/2040 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201799480; called by muse, mutect2
- LAMA4 | c.198A>G p.K66= | Splice Region (SNP) | VAF 39/788 reads (5%) | called by muse, mutect2
- CLUL1 | c.9G>A p.P3= | Silent (SNP) | VAF 56/1556 reads (4%) | catalogued as rs1209650971, COSV58112964; called by muse, mutect2
